Somatic mutation profile of tumor specimen HTMCP-03-06-02408-01A (aliquot HTMCP-03-06-02408-01A-01D-10409) from CGCI case HTMCP-03-06-02408, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3.
Specimen HTMCP-03-06-02408-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ad8b474-0a20-43fa-bd52-a8af25e752a9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02408-10A (Blood Derived Normal), aliquot HTMCP-03-06-02408-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb8ee362-1718-4138-bd1e-443208ad0ca0

The open-access MAF lists 118 somatic variants for this specimen: 82 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 32, Nonsense Mutation 10, Intron 4, Splice Region 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 17/107 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: drug response / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGB | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV58860456; called by muse, mutect2, varscan2
- ARID1A | c.1350G>A p.Q450= | Splice Region (SNP) | VAF 5/19 reads (26%) | catalogued as COSV61389842; called by muse, mutect2, varscan2
- BLM | c.4142C>T p.S1381L | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs1277229461; called by muse, varscan2
- C11orf80 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 78/306 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.149); catalogued as rs1176308748; called by muse, mutect2, varscan2
- CCDC105 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.691); catalogued as rs952698685; called by muse, mutect2, varscan2
- CDH20 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53005454; called by muse, mutect2, varscan2
- CHD2 | c.1927C>G p.L643V | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67715426; called by muse, mutect2, varscan2
- CHL1 | c.926G>A p.R309H (on ENST00000397491 / NM_001253387.1; = p.R325H on NM_006614.4) | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs201671256; called by muse, mutect2, varscan2
- COL5A2 | c.3379C>T p.R1127C | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886055354, COSV66407318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL4B | c.1414G>T p.D472Y | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60689381, COSV60690821; called by muse, mutect2, varscan2
- DDX60L | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as rs779359195; called by muse, mutect2, varscan2
- DENND4A | c.3215C>G p.S1072* | Nonsense Mutation (SNP) | VAF 66/273 reads (24%) | catalogued as COSV71267233; called by muse, mutect2, varscan2
- DHPS | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as rs1487190370; called by muse, mutect2
- EPC2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.931); catalogued as COSV99309965; called by muse, mutect2, varscan2
- HDAC7 | c.2191C>T p.R731C (on ENST00000427332; = p.R770C on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV50334951; called by muse, mutect2, varscan2
- IARS1 | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 35/143 reads (24%) | catalogued as COSV65114662, COSV65115406; called by muse, mutect2, varscan2
- IFT122 | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56202633, COSV99959668; called by muse, varscan2
- LAMA3 | c.4244G>C p.G1415A | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV58062285, COSV58072601; called by muse, mutect2, varscan2
- LPA | c.4126G>C p.E1376Q | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV60305501; called by muse, mutect2, varscan2
- LRRC7 | c.1981G>A p.E661K (on ENST00000651989 / NM_001370785.2; = p.E628K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs200158661, COSV50435197; called by muse, mutect2, varscan2
- MAML3 | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.194); catalogued as rs1469040438; called by muse, varscan2
- MUC16 | c.37007C>G p.T12336S | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.986); catalogued as COSV67479248; called by muse, mutect2, varscan2
- PCDHGA10 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.125); catalogued as rs1012028735, COSV53960814; called by muse, mutect2, varscan2
- PDE4DIP | c.2741G>A p.R914H | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as rs782300605, COSV57734313; called by muse, mutect2, varscan2
- PROM1 | c.1494G>A p.M498I | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71699157; called by muse, mutect2, varscan2
- RASA1 | c.3100C>T p.Q1034* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV56924198; called by muse, mutect2, varscan2
- SIPA1L3 | c.1972G>A p.G658S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753399028; called by muse, varscan2
- SSH2 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); catalogued as rs747806416, COSV52177700; called by muse, mutect2, varscan2
- TAF1 | c.3004C>T p.R1002C (on ENST00000373790 / NM_138923.4; = p.R1023C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52114997, COSV52118430; called by muse, mutect2, varscan2
- TCF20 | c.1775C>T p.S592L | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV59494819; called by muse, varscan2
- THADA | c.2433G>A p.M811I | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as rs752366089, COSV57683771; called by muse, mutect2, varscan2
- USH1C | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368903400; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WNK2 | c.6545C>T p.T2182M (on ENST00000297954 / NM_001282394.1; = p.T2145M on NM_006648.3) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs771040278; called by muse, mutect2, varscan2
- ZNF423 | c.1457C>G p.S486C (on ENST00000563137 / NM_001379286.1; = p.S478C on NM_015069.4) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.21); catalogued as COSV52198548, COSV99284221; called by muse, mutect2, varscan2
- ZNF729 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 86/293 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as rs891862927; called by muse, mutect2, varscan2
- ZZEF1 | c.7455C>G p.Y2485* | Nonsense Mutation (SNP) | VAF 38/130 reads (29%) | catalogued as COSV67557200; called by muse, mutect2, varscan2
- AFF4 | c.2210C>T p.P737L | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ARHGEF7 | c.1409A>T p.E470V (on ENST00000375741 / NM_001113511.2; = p.E292V on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BPTF | c.4739C>T p.S1580L | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.024); called by muse, mutect2
- CCDC38 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- CDK12 | c.1969_1971delinsAA p.E657Kfs*96 | Frame Shift Del (DEL) | VAF 55/192 reads (29%) | called by pindel, varscan2*
- CELSR3 | c.9317A>C p.D3106A | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- CLSTN1 | c.1359C>T p.V453= (on ENST00000377298 / NM_001009566.3; = p.V443= on NM_014944.4) | Splice Region (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- COL6A6 | c.4396G>C p.D1466H | Missense Mutation (SNP) | VAF 63/297 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- CUBN | c.4933C>G p.Q1645E | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- DENND4B | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- EDC4 | c.2390G>C p.G797A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EIF3K | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- FAT4 | c.8350C>A p.P2784T | Missense Mutation (SNP) | VAF 95/364 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- HERC2 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- LIMA1 | c.1994G>A p.R665K | Missense Mutation (SNP) | VAF 161/446 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRBA | c.2153G>T p.R718M | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MACF1 | c.4525G>A p.E1509K | Missense Mutation (SNP) | VAF 23/103 reads (22%) | called by muse, mutect2, varscan2
- MALRD1 | c.5280T>G p.I1760M | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- MAP4K4 | c.3235G>A p.E1079K (on ENST00000347699 / NM_001242559.2; = p.E997K on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MARCHF6 | c.848C>A p.S283* | Nonsense Mutation (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- MUC16 | c.30428C>G p.S10143C | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- MYO9A | c.2949C>A p.F983L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- NOVA1 | c.179C>G p.A60G | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- PCNT | c.5008G>C p.E1670Q | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PDE3A | c.3273A>T p.E1091D | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- PSME4 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- RABGAP1L | c.677C>T p.A226V (on ENST00000489615 / NM_001243765.2; = p.A109V on NM_001243764.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- RAD51D | c.938C>A p.T313N | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPGRIP1L | c.3757G>T p.E1253* | Nonsense Mutation (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- SMC1B | c.882G>C p.K294N | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- STON2 | c.2561G>T p.R854L (on ENST00000649389 / NM_001366849.2; = p.R797L on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TCF20 | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TCF20 | c.1724C>G p.P575R | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); called by muse, varscan2
- TCF20 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 55/208 reads (26%) | called by muse, varscan2
- TCF20 | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 40/150 reads (27%) | called by muse, varscan2
- TCF20 | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 72/272 reads (26%) | called by muse, varscan2
- TMPO | c.407G>C p.G136A | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- TSC1 | c.364A>G p.M122V | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTF2 | c.2382G>C p.W794C | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBAP2L | c.515G>C p.R172T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- UGGT2 | c.2624G>A p.S875N | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- USP32 | c.2578G>A p.D860N | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- ZKSCAN5 | c.2376G>T p.Q792H | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ZNF157 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZNF829 | c.376C>G p.Q126E | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AKAP11 | c.4653T>G p.T1551= | Silent (SNP) | VAF 105/283 reads (37%) | called by muse, mutect2, varscan2
- ANKRD24 | c.6G>A p.K2= | Silent (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2
- ARHGAP31 | c.1980G>C p.L660= | Silent (SNP) | VAF 32/153 reads (21%) | called by muse, mutect2, varscan2
- BBX | c.2760C>G p.L920= (on ENST00000325805 / NM_001142568.3; = p.L890= on NM_020235.7) | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as COSV57879388; called by muse, mutect2, varscan2
- BRINP3 | c.513G>A p.S171= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as COSV66543151; called by muse, mutect2, varscan2
- CDK16 | c.1401G>A p.E467= | Silent (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- CLASP2 | c.3177G>C p.R1059= (on ENST00000359576; = p.R1058= on NM_015097.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 31/103 reads (30%) | called by muse, mutect2, varscan2
- COLGALT2 | c.879C>T p.P293= | Silent (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- DIP2B | c.4635C>T p.I1545= | Silent (SNP) | VAF 58/269 reads (22%) | called by muse, mutect2, varscan2
- DLC1 | c.4014G>A p.E1338= (on ENST00000276297 / NM_001348081.2; = p.E901= on NM_006094.5) | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs375361935; called by muse, mutect2, varscan2
- ELFN1 | c.555C>T p.C185= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as rs899849370; called by muse, mutect2, varscan2
- EPHA6 | c.2904G>A p.E968= | Silent (SNP) | VAF 33/194 reads (17%) | catalogued as COSV67587218, COSV67591992; called by muse, mutect2, varscan2
- F5 | c.1035G>T p.R345= | Silent (SNP) | VAF 57/210 reads (27%) | catalogued as COSV63122030; called by muse, mutect2, varscan2
- FSHR | c.1659C>T p.Y553= | Silent (SNP) | VAF 66/266 reads (25%) | called by muse, mutect2, varscan2
- GLYATL2 | c.33G>A p.Q11= | Silent (SNP) | VAF 37/169 reads (22%) | called by muse, mutect2, varscan2
- HTR1A | c.987C>T p.A329= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs764194436, COSV60500844; called by muse, mutect2, varscan2
- IGDCC3 | c.330G>A p.S110= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as rs769811625, COSV60080668; called by muse, mutect2, varscan2
- KIF16B | c.1716C>T p.F572= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as rs1218040714; called by muse, mutect2, varscan2
- MYH4 | c.3966G>A p.Q1322= | Silent (SNP) | VAF 22/215 reads (10%) | called by muse, mutect2, varscan2
- MYH7 | c.549G>T p.G183= | Silent (SNP) | VAF 30/100 reads (30%) | called by muse, mutect2, varscan2
- RPGRIP1L | c.903C>T p.I301= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs1240279456; called by muse, mutect2, varscan2
- RTEL1 | c.3249G>C p.L1083= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs757422439; called by muse, mutect2, varscan2
- SOX30 | c.525C>G p.L175= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- TCF20 | c.2631C>T p.V877= | Silent (SNP) | VAF 40/156 reads (26%) | catalogued as COSV59488477; called by muse, varscan2
- TCF20 | c.2580C>T p.L860= | Silent (SNP) | VAF 52/210 reads (25%) | catalogued as rs147254163; called by muse, varscan2
- TCF20 | c.1254C>G p.L418= | Silent (SNP) | VAF 78/274 reads (28%) | catalogued as rs1488199816; called by muse, mutect2, varscan2
- TCF20 | c.90C>T p.F30= | Silent (SNP) | VAF 29/136 reads (21%) | called by muse, mutect2, varscan2
- TMEM8B | c.957G>A p.V319= | Silent (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- UBR4 | c.5352G>A p.K1784= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV64384342; called by muse, mutect2, varscan2
- USP21 | c.690G>A p.L230= | Silent (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- XKR7 | c.381C>T p.V127= | Silent (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- ZNF804B | c.2145C>T p.S715= | Silent (SNP) | VAF 51/278 reads (18%) | catalogued as rs762121098; called by muse, mutect2, varscan2
- COLEC11 | c.203-11456G>C | Intron (SNP) | VAF 61/155 reads (39%) | catalogued as COSV52591434, COSV99363348; called by muse, mutect2, varscan2
- CTNNA2 | c.1057-79583G>A | Intron (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- PTPN6 | c.1674-28G>A | Intron (SNP) | VAF 33/121 reads (27%) | catalogued as rs782668534; called by muse, mutect2, varscan2
- WT1 | c.1063-10C>G | Intron (SNP) | VAF 29/99 reads (29%) | called by muse, mutect2, varscan2
